Somatic mutation profile of tumor specimen C3N-03888-02 (aliquot CPT0222180006) from CPTAC case C3N-03888, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 58.8 years (21,474 days).
Specimen C3N-03888-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa840ebc-c178-4e0d-9b2d-9e706f711dd8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03888-71 (Blood Derived Normal), aliquot CPT0222290002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3abaddcb-9c5a-4591-adae-651f73e21986

The open-access MAF lists 143 somatic variants for this specimen: 94 protein-altering or splice-affecting, 31 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 31, Intron 10, Nonsense Mutation 6, Frame Shift Del 4, 5'UTR 3, 3'UTR 2, RNA 1, Frame Shift Ins 1, Splice Site 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 323/651 reads (50%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS3 | c.602A>G p.Y201C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771017077, COSV99711735; called by muse, mutect2, varscan2
- ANO7 | c.1612G>A p.A538T (on ENST00000274979; = p.A484T on NM_001370694.2) | Missense Mutation (SNP) | VAF 57/230 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs758652317, COSV51476201; called by muse, mutect2, varscan2
- APLP1 | c.1784C>T p.S595F (on ENST00000221891 / NM_001024807.3; = p.S594F on NM_005166.4) | Missense Mutation (SNP) | VAF 24/223 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV99697557; called by muse, mutect2, varscan2
- ASB16 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 83/549 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs531721947; called by muse, mutect2, varscan2
- ASIC5 | c.1078T>C p.F360L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV73333062; called by muse, mutect2, varscan2
- CAPN2 | c.1582G>C p.D528H | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.264); catalogued as COSV54338084; called by muse, mutect2, varscan2
- CEP295 | c.5650G>A p.E1884K | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs1161558705; called by muse, mutect2, varscan2
- CHD6 | c.3190G>A p.E1064K | Missense Mutation (SNP) | VAF 48/289 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as rs1388279313; called by muse, mutect2, varscan2
- CLTCL1 | c.2806G>A p.E936K | Missense Mutation (SNP) | VAF 17/226 reads (8%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.595); catalogued as rs1275164960; called by muse, mutect2
- CTNND1 | c.1823C>T p.A608V | Missense Mutation (SNP) | VAF 27/303 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs1238818682; called by muse, mutect2
- DAAM2 | c.1691G>A p.G564E | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.147); catalogued as rs766554509; called by muse, varscan2
- EHBP1 | c.2203G>C p.E735Q | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); catalogued as COSV50423981, COSV99861401; called by muse, mutect2, varscan2
- ERVW-1 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 160/262 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs758687766, COSV101423821; called by muse, mutect2, varscan2
- FAM20C | c.1654G>A p.V552I | Missense Mutation (SNP) | VAF 116/363 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs753843872; called by muse, mutect2, varscan2
- GP2 | c.931G>A p.D311N (on ENST00000381362 / NM_001007240.3; = p.D308N on NM_001502.4) | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); catalogued as COSV56895359; called by muse, mutect2
- GRIN2B | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 15/506 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.561); catalogued as rs1321997898; called by muse, mutect2
- GRIP1 | c.2743G>C p.D915H (on ENST00000359742 / NM_001379345.1; = p.D863H on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/358 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.751); catalogued as rs1488492679; called by mutect2, varscan2
- HDAC9 | c.2245G>A p.G749S | Missense Mutation (SNP) | VAF 59/325 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs779864864, COSV67773457; called by muse, mutect2, varscan2
- LRFN3 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99873684; called by muse, mutect2, varscan2
- MGAM2 | c.4575G>A p.W1525* | Nonsense Mutation (SNP) | VAF 32/184 reads (17%) | catalogued as rs1014638754; called by muse, mutect2, varscan2
- MYH14 | c.5059G>C p.E1687Q | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as COSV51834294; called by muse, mutect2, varscan2
- NUCB1 | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs143826495; called by muse, mutect2, varscan2
- OR6C3 | c.612G>C p.L204F | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as rs1565665130; called by muse, mutect2
- PBX1 | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1558022514, COSV63342493; called by muse, mutect2, varscan2
- PPP1R16A | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 110/683 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs762667060, COSV52954016; called by muse, mutect2, varscan2
- PPP1R42 | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764178286; called by muse, mutect2, varscan2
- PSME2 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.179); catalogued as rs200493276; called by muse, mutect2, varscan2
- RPTN | c.2335G>A p.E779K | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs1019810114, COSV60166727; called by muse, mutect2, varscan2
- RYR2 | c.1357A>G p.S453G | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.67); catalogued as COSV63675761; called by muse, mutect2
- SDC4 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1188172692; called by muse, mutect2
- SHANK1 | c.1505G>A p.R502Q | Missense Mutation (SNP) | VAF 69/306 reads (23%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.886); catalogued as rs766019271; called by muse, mutect2, varscan2
- SLC9A8 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs779814701, COSV64288462; called by muse, mutect2, varscan2
- TRPS1 | c.1079A>G p.N360S (on ENST00000220888 / NM_001330599.2; = p.N373S on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/242 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV99634715; called by muse, mutect2, varscan2
- TULP4 | c.1699C>T p.R567W | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1262105765, COSV65581909; called by muse, mutect2, varscan2
- UNC13D | c.772del p.D258Tfs*70 | Frame Shift Del (DEL) | VAF 67/304 reads (22%) | catalogued as COSV52885526; called by mutect2, pindel, varscan2
- USP35 | c.1259C>T p.S420L | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs562246864, COSV71573298; called by muse, mutect2, varscan2
- ZC3H12C | c.2353G>A p.D785N | Missense Mutation (SNP) | VAF 88/255 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as COSV53708474; called by muse, mutect2, varscan2
- ADGRG1 | c.1622A>T p.N541I | Missense Mutation (SNP) | VAF 97/584 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ALAS1 | c.105G>C p.K35N | Missense Mutation (SNP) | VAF 10/269 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.356); called by muse, mutect2
- ANKRD18A | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 98/426 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ANKRD28 | c.2399_2409del p.N800Sfs*2 | Frame Shift Del (DEL) | VAF 12/104 reads (12%) | called by mutect2, pindel
- ATP7A | c.3764G>C p.G1255A | Missense Mutation (SNP) | VAF 57/105 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- BICC1 | c.446G>A p.G149D | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA1I | c.5074A>G p.T1692A | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- CADM1 | c.1228G>T p.E410* | Nonsense Mutation (SNP) | VAF 22/548 reads (4%) | called by muse, mutect2
- CCDC120 | c.1768C>T p.L590F | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- CCDC121 | c.194G>T p.S65I | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- CEP164 | c.293A>C p.Q98P | Missense Mutation (SNP) | VAF 24/572 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- CHD1L | c.2657A>G p.Q886R | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- CNTN5 | c.1846T>G p.F616V | Missense Mutation (SNP) | VAF 9/232 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); called by muse, mutect2
- DISP1 | c.3219del p.F1074Sfs*3 | Frame Shift Del (DEL) | VAF 38/161 reads (24%) | called by mutect2, pindel, varscan2
- DTX4 | c.494C>T p.T165I | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.058); called by muse, mutect2
- EDEM3 | c.2635G>A p.E879K | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ELL3 | c.593G>C p.R198T | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- EXD3 | c.1173+1G>T p.X391_splice | Splice Site (SNP) | VAF 34/170 reads (20%) | called by muse, mutect2, varscan2
- FAM98A | c.914G>C p.R305T | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); called by muse, mutect2
- FOXD1 | c.622dup p.M208Nfs*254 | Frame Shift Ins (INS) | VAF 132/472 reads (28%) | called by mutect2, pindel, varscan2
- FREM3 | c.1387G>C p.D463H | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- GRIA3 | c.2529G>C p.L843F | Missense Mutation (SNP) | VAF 73/169 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- HS3ST3A1 | c.502C>G p.L168V | Missense Mutation (SNP) | VAF 62/450 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- HS3ST4 | c.972C>G p.I324M | Missense Mutation (SNP) | VAF 30/278 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- JPH1 | c.1721G>T p.S574I | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KIF26B | c.3296C>A p.P1099Q | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC70 | c.1556A>T p.Q519L | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, varscan2
- NOD2 | c.3086A>G p.D1029G | Missense Mutation (SNP) | VAF 87/414 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- NUP153 | c.1493C>G p.S498C | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.08); called by muse, mutect2
- OR13J1 | c.437G>C p.G146A | Missense Mutation (SNP) | VAF 49/197 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- OR1E2 | c.405C>G p.I135M | Missense Mutation (SNP) | VAF 47/280 reads (17%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2, varscan2
- OR4M1 | c.578T>A p.F193Y | Missense Mutation (SNP) | VAF 91/593 reads (15%) | SIFT tolerated (1); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- OR5AC2 | c.102G>C p.L34F | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- OR8B2 | c.425C>G p.S142C | Missense Mutation (SNP) | VAF 25/298 reads (8%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- PCDHA1 | c.1054G>T p.V352F | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- POLQ | c.221G>A p.W74* | Nonsense Mutation (SNP) | VAF 31/162 reads (19%) | called by muse, mutect2, varscan2
- RUNX3 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLC25A23 | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- SMARCA1 | c.2857C>T p.Q953* | Nonsense Mutation (SNP) | VAF 6/9 reads (67%) | called by muse, mutect2, varscan2
- TACR3 | c.348G>T p.M116I | Missense Mutation (SNP) | VAF 85/497 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TP53 | c.856_882del p.E286_E294del | In Frame Del (DEL) | VAF 235/703 reads (33%) | called by mutect2, pindel, varscan2
- TPM2 | c.473C>G p.S158* | Nonsense Mutation (SNP) | VAF 193/841 reads (23%) | called by muse, mutect2, varscan2
- TRAF7 | c.1831C>T p.P611S | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- TRPM8 | c.296C>G p.P99R | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- TRPV6 | c.1264_1267del p.D422Ifs*9 | Frame Shift Del (DEL) | VAF 48/303 reads (16%) | called by mutect2, pindel, varscan2
- TTF1 | c.1420A>G p.I474V | Missense Mutation (SNP) | VAF 87/384 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTLL4 | c.496A>T p.M166L | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UNC5D | c.1698A>G p.I566M | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- USP11 | c.1702G>A p.D568N (on ENST00000218348; = p.D525N on NM_001371072.1) | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP28 | c.2398A>G p.K800E | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- VGF | c.469G>C p.E157Q | Missense Mutation (SNP) | VAF 19/289 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- WDR97 | c.4739C>T p.P1580L | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- YIPF4 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZFHX2 | c.6505C>G p.Q2169E | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); called by muse, mutect2
- ZNF12 | c.1809A>T p.K603N (on ENST00000405858 / NM_016265.4; = p.K565N on NM_006956.3) | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF286A | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- AARD | c.129G>A p.T43= | Silent (SNP) | VAF 96/593 reads (16%) | catalogued as rs202038557; called by muse, mutect2, varscan2
- ASAP2 | c.375C>T p.F125= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs768708463, COSV55633467; called by muse, mutect2, varscan2
- BBS2 | c.207C>T p.L69= | Silent (SNP) | VAF 56/280 reads (20%) | catalogued as COSV55325144; called by muse, mutect2, varscan2
- CCSER1 | c.2619A>G p.L873= | Silent (SNP) | VAF 24/93 reads (26%) | called by muse, mutect2, varscan2
- CLEC4M | c.264A>G p.A88= | Silent (SNP) | VAF 94/409 reads (23%) | catalogued as rs1826305; called by muse, varscan2
- COL8A2 | c.675C>T p.P225= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs376838244; called by muse, mutect2, varscan2
- CSMD1 | c.1824C>T p.N608= (on ENST00000520002; = p.N607= on NM_033225.6) | Silent (SNP) | VAF 30/139 reads (22%) | catalogued as rs375948878; called by muse, mutect2, varscan2
- DAGLA | c.123C>T p.F41= | Silent (SNP) | VAF 52/316 reads (16%) | catalogued as rs972629226, COSV57195035; called by muse, mutect2, varscan2
- EYA1 | c.1530G>A p.A510= | Silent (SNP) | VAF 34/275 reads (12%) | catalogued as rs147434089; called by muse, mutect2, varscan2
- FBXO48 | c.342G>A p.V114= | Silent (SNP) | VAF 17/127 reads (13%) | called by muse, mutect2, varscan2
- FPR3 | c.775C>T p.L259= | Silent (SNP) | VAF 17/89 reads (19%) | called by muse, mutect2, varscan2
- GSE1 | c.1059T>A p.A353= | Silent (SNP) | VAF 101/407 reads (25%) | called by muse, mutect2, varscan2
- HR | c.1626A>C p.P542= | Silent (SNP) | VAF 59/300 reads (20%) | called by muse, mutect2, varscan2
- HSD17B11 | c.153G>A p.L51= | Silent (SNP) | VAF 31/278 reads (11%) | called by muse, mutect2, varscan2
- HSD17B13 | c.519G>A p.V173= | Silent (SNP) | VAF 20/144 reads (14%) | called by muse, mutect2, varscan2
- LAMA1 | c.7011A>G p.S2337= | Silent (SNP) | VAF 75/309 reads (24%) | called by muse, mutect2, varscan2
- LCK | c.114C>T p.I38= | Silent (SNP) | VAF 12/55 reads (22%) | called by muse, varscan2
- LLGL1 | c.2277G>A p.V759= | Silent (SNP) | VAF 48/291 reads (16%) | called by muse, mutect2, varscan2
- MROH5 | c.459C>T p.I153= | Silent (SNP) | VAF 27/245 reads (11%) | catalogued as rs754615893, COSV71302423; called by muse, mutect2, varscan2
- NEXMIF | c.3126G>A p.E1042= | Silent (SNP) | VAF 42/176 reads (24%) | called by muse, mutect2, varscan2
- NFXL1 | c.1605G>A p.V535= | Silent (SNP) | VAF 35/189 reads (19%) | called by muse, mutect2, varscan2
- OR10AG1 | c.225C>T p.D75= | Silent (SNP) | VAF 16/114 reads (14%) | called by muse, mutect2, varscan2
- OTOP3 | c.1026C>T p.I342= | Silent (SNP) | VAF 88/431 reads (20%) | catalogued as rs78168725, COSV60915254; called by muse, mutect2, varscan2
- PTGIR | c.843C>T p.Y281= | Silent (SNP) | VAF 72/271 reads (27%) | catalogued as rs778174017, COSV52191410; called by muse, mutect2, varscan2
- PUM2 | c.2478C>T p.D826= | Silent (SNP) | VAF 34/126 reads (27%) | called by muse, mutect2
- SCLY | c.1203G>A p.G401= (on ENST00000651534; = p.G393= on NM_016510.7) | Silent (SNP) | VAF 27/122 reads (22%) | catalogued as rs765893713; called by muse, mutect2
- SHOC2 | c.1272C>T p.L424= | Silent (SNP) | VAF 31/174 reads (18%) | catalogued as rs144379168; called by muse, mutect2, varscan2
- SLC1A5 | c.1068G>A p.T356= | Silent (SNP) | VAF 12/69 reads (17%) | called by muse, mutect2, varscan2
- USP48 | c.1023C>G p.V341= | Silent (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- ZDBF2 | c.6684G>A p.S2228= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs769931510, COSV100985602, COSV65624129; called by muse, mutect2, varscan2
- ZNF765 | c.444G>A p.L148= | Silent (SNP) | VAF 17/155 reads (11%) | called by muse, mutect2, varscan2
- AAMDC | c.-18-1295T>C | Intron (SNP) | VAF 18/84 reads (21%) | called by muse, mutect2, varscan2
- AC139530.2 | c.-62G>A | 5'UTR (SNP) | VAF 16/164 reads (10%) | catalogued as rs1033431867; called by muse, mutect2
- AGTPBP1 | c.-93A>G | 5'UTR (SNP) | VAF 39/131 reads (30%) | called by muse, mutect2, varscan2
- ALPK1 | c.475+2240G>C | Intron (SNP) | VAF 16/150 reads (11%) | called by muse, mutect2, varscan2
- AOC1 | c.1857-53G>C | Intron (SNP) | VAF 18/111 reads (16%) | catalogued as rs1237130816; called by muse, mutect2, varscan2
- C5orf22 | c.1060-2787C>T | Intron (SNP) | VAF 19/92 reads (21%) | called by muse, mutect2, varscan2
- CCM2 | c.-13C>T | 5'UTR (SNP) | VAF 4/26 reads (15%) | catalogued as rs1188034637; called by muse, mutect2
- DCHS2 | n.7346C>T | RNA (SNP) | VAF 23/127 reads (18%) | called by muse, mutect2, varscan2
- FGFR1 | c.92-10361G>A | Intron (SNP) | VAF 45/666 reads (7%) | catalogued as rs765132888, COSV58339455; called by muse, mutect2
- KLF6 | c.*1543G>A | 3'UTR (SNP) | VAF 23/87 reads (26%) | called by muse, mutect2, varscan2
- LPIN1 | c.2141+48G>A | Intron (SNP) | VAF 61/278 reads (22%) | catalogued as rs754512577; called by muse, mutect2, varscan2
- MON2 | chr12:62603218 C>T | 3'Flank (SNP) | VAF 21/99 reads (21%) | called by muse, mutect2, varscan2
- MTA1 | c.1814-1137T>G | Intron (SNP) | VAF 29/188 reads (15%) | catalogued as rs1272285090; called by muse, mutect2, varscan2
- NDUFS3 | chr11:47579043 C>G | 5'Flank (SNP) | VAF 18/448 reads (4%) | called by muse, mutect2
- PEX19 | c.*2284G>A | 3'UTR (SNP) | VAF 56/249 reads (22%) | called by muse, mutect2, varscan2
- PRR12 | c.52-465C>G | Intron (SNP) | VAF 95/432 reads (22%) | called by muse, mutect2, varscan2
- RAP1GAP | c.1429-887G>T | Intron (SNP) | VAF 68/370 reads (18%) | called by muse, varscan2
- SYVN1 | c.1234+25C>T | Intron (SNP) | VAF 32/120 reads (27%) | called by muse, mutect2, varscan2
